CPTAC case C3L-00987 — Other and unspecified parts of tongue — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b80b7a5b-fe1c-439d-b3cb-981dd2cc295b

Demographics
Sex at birth: male; Race: white; Year of birth: 1955; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Tongue, NOS; Age at diagnosis: 61.4 years (22,430 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 429 days (1.2 years); Days to last follow up: 429 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 7; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 429 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 2.

Other clinical attributes
- Weight: 80 kg; Height: 182 cm; BMI: 24.15.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 43; Cigarettes per day: 20; Tobacco smoking onset year: 1973; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 49; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00987-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Initial weight: 400 mg; Time between clamping and freezing: 28 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00987-21: Section location: Tongue; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-00987-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -4 days; Time between clamping and freezing: 28 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00987-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -4 days; Method of sample procurement: Blood Draw.
